Somatic mutation profile of tumor specimen 0DC9V0 from CCDI case PBBLXV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 17.1 years (6,231 days).
Specimen 0DC9V0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7662dbf3-8edb-4af0-b99e-9ccc436d9345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC9UX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ba31cca-e8d5-4952-856f-e00b373e392b

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, 5'UTR 2, RNA 2, Splice Region 1, Intron 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 760/815 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, mutect2, varscan2
- ABCA13 | c.4541C>A p.A1514E | Missense Mutation (SNP) | VAF 375/963 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs117812446; called by muse, mutect2, varscan2
- FAT2 | c.4945C>T p.H1649Y | Missense Mutation (SNP) | VAF 340/1465 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as rs936660504; called by muse, mutect2, varscan2
- GPM6A | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 338/778 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); catalogued as rs1025501758, COSV54555903; called by muse, mutect2, varscan2
- INPPL1 | c.3201dup p.S1068Qfs*17 | Frame Shift Ins (INS) | VAF 222/368 reads (60%) | catalogued as COSV53354954; called by mutect2, varscan2
- KMT5A | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 362/1003 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs368237921; called by muse, mutect2, varscan2
- KYNU | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 390/911 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489023975; called by muse, varscan2
- OXGR1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 332/846 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs752266769; called by muse, mutect2, varscan2
- AGBL2 | c.2252del p.K751Rfs*19 | Frame Shift Del (DEL) | VAF 516/1283 reads (40%) | called by mutect2, varscan2
- CPEB2 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- CYP2W1 | c.881T>G p.V294G | Missense Mutation (SNP) | VAF 274/599 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FNBP1 | c.1014T>A p.H338Q | Missense Mutation (SNP) | VAF 159/401 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FOXP1 | c.1530+5G>A | Splice Region (SNP) | VAF 30/726 reads (4%) | called by muse, mutect2
- GAREM2 | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 196/471 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPXN | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 287/703 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MEFV | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 279/677 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RXFP2 | c.1428A>G p.I476M | Missense Mutation (SNP) | VAF 488/1216 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC27A6 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 221/521 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPPK1 | c.7770C>T p.D2590= | Silent (SNP) | VAF 46/301 reads (15%) | catalogued as rs1484220930; called by muse, mutect2, varscan2
- MYF6 | c.354G>A p.R118= | Silent (SNP) | VAF 149/300 reads (50%) | catalogued as rs758461667; called by muse, mutect2, varscan2
- PCDHB16 | c.2130G>A p.A710= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs549792075, COSV99501612; called by muse, mutect2
- PPP2R5B | c.1455G>T p.R485= | Silent (SNP) | VAF 158/427 reads (37%) | called by muse, mutect2, varscan2
- DNM1 | c.2534+39C>T | Intron (SNP) | VAF 509/874 reads (58%) | catalogued as rs1442040713; called by muse, mutect2, varscan2
- GOLGA6L3 | n.1633C>T | RNA (SNP) | VAF 7/55 reads (13%) | called by mutect2, varscan2
- MUC19 | n.12210C>A | RNA (SNP) | VAF 432/1005 reads (43%) | called by muse, varscan2
- TUBA1C | c.-84A>G | 5'UTR (SNP) | VAF 158/286 reads (55%) | called by muse, mutect2, varscan2
- ZZZ3 | c.-87T>C | 5'UTR (SNP) | VAF 403/1004 reads (40%) | called by muse, mutect2, varscan2
